Somatic mutation profile of tumor specimen TCGA-AA-3877-01A (aliquot TCGA-AA-3877-01A-01W-0995-10) from TCGA case TCGA-AA-3877, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage I; Age at diagnosis: 83.2 years (30,377 days).
Specimen TCGA-AA-3877-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbdf5164-9433-4e9c-966b-3a969bec15d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3877-10A (Blood Derived Normal), aliquot TCGA-AA-3877-10A-01W-1982-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e5c7f21-a56f-4578-ba98-a9f0bf6f9992

The open-access MAF lists 1,349 somatic variants for this specimen: 999 protein-altering or splice-affecting, 332 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 706, Silent 332, Frame Shift Del 182, Nonsense Mutation 32, Frame Shift Ins 32, Splice Site 19, In Frame Del 13, Splice Region 13, Intron 12, 3'UTR 4, Translation Start Site 2, RNA 2.

Variants (750 of 1,349; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs752992432, CM092737, COSV55590188, COSV99792711; ClinVar: likely pathogenic; called by muse, varscan2
- ABCC8 | c.4612C>T p.R1538* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs1411638309, COSV56852422; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1569541088, CM014158, CM950050, COSV99497841; ClinVar: pathogenic; called by muse, mutect2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKL5 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 280/973 reads (29%) | catalogued as rs62653623, CM063890, COSV66112951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.3713del p.K1238Rfs*6 | Frame Shift Del (DEL) | VAF 721/3119 reads (23%) | catalogued as rs1557362198; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IDS | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs104894860, CM920366, COSV100558135; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MPO | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs119469013, CM044668, COSV99832929; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.397dup p.H133Pfs*7 | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 229/777 reads (29%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NR1H4 | c.953dup p.L319Afs*10 (on ENST00000551379 / NM_001206993.2; = p.L305Afs*10 on NM_005123.4) | Frame Shift Ins (INS) | VAF 5/27 reads (19%) | catalogued as rs770757947; ClinVar: likely pathogenic; called by pindel, varscan2
- PAH | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 91/326 reads (28%) | catalogued as rs62642910, CM990998, COSV100188344; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 33/121 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100588886; called by muse, varscan2
- AARS1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369366275; called by muse, mutect2, varscan2
- ABCA13 | c.2010del p.P671Lfs*15 | Frame Shift Del (DEL) | VAF 55/265 reads (21%) | catalogued as rs758897835; called by mutect2, pindel, varscan2
- ABCA8 | c.3986C>T p.A1329V | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs776271867, COSV99285368; called by muse, mutect2, varscan2
- ABCC1 | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs765498811, COSV60680329; called by muse, mutect2, varscan2
- ABCC11 | c.3682C>A p.L1228I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100751028; called by muse, mutect2, varscan2
- ABCD4 | c.1684C>T p.L562F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs746372602, COSV53993823; called by muse, mutect2, varscan2
- ABCG1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1362774007, COSV100494409; called by muse, mutect2, varscan2
- ABCG4 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100266954; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs749606695; called by mutect2, varscan2
- AC004922.1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.946); catalogued as rs1209496423, COSV99501349; called by muse, mutect2
- AC097636.1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371775341; called by muse, mutect2, varscan2
- ACBD3 | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as COSV100831115; called by muse, mutect2, varscan2
- ACCS | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs957027087, COSV99772938; called by muse, mutect2, varscan2
- ACOT7 | c.976G>A p.A326T (on ENST00000377855 / NM_181864.3; = p.A316T on NM_007274.4) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.097); catalogued as COSV100830260; called by muse, mutect2, varscan2
- ACTL6B | c.369G>A p.P123= | Splice Region (SNP) | VAF 54/297 reads (18%) | catalogued as rs746247865, COSV50519582; called by muse, mutect2, varscan2
- ACVR1B | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV57779763; called by muse, mutect2, varscan2
- ADAM29 | c.1198T>A p.C400S | Missense Mutation (SNP) | VAF 113/493 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100822195; called by muse, mutect2, varscan2
- ADAMTS1 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs749859601, COSV53172434; called by muse, mutect2
- ADAMTS12 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 163/540 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375250179; called by muse, mutect2, varscan2
- ADAMTS12 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as COSV100711524, COSV61261596; called by muse, mutect2, varscan2
- ADAMTS3 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs763687444, COSV54398813; called by muse, mutect2, varscan2
- ADCY5 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 122/395 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs771319042, COSV100567953, COSV59195474; called by muse, mutect2, varscan2
- ADCY6 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs777764949, COSV100326801; called by muse, mutect2
- ADGRE1 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs375715052; called by muse, mutect2
- ADGRF3 | c.1190C>T p.P397L (on ENST00000311519 / NM_001145168.1; = p.P198L on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs759947684, COSV100274655, COSV61049754; called by muse, mutect2, varscan2
- ADGRL4 | c.1893G>T p.W631C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876412; called by muse, mutect2, varscan2
- ADGRV1 | c.3562A>G p.I1188V | Missense Mutation (SNP) | VAF 137/425 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs767721447, COSV101316320; called by muse, mutect2, varscan2
- AGPAT3 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52373377; called by muse, mutect2, varscan2
- AGT | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as COSV100794464; called by muse, mutect2, varscan2
- AKAP9 | c.7078A>G p.S2360G (on ENST00000359028; = p.S2336G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV100662854; called by muse, mutect2, varscan2
- ALDH7A1 | c.915C>A p.A305= | Splice Region (SNP) | VAF 16/48 reads (33%) | catalogued as COSV101302005; called by muse, mutect2, varscan2
- ALOX12 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99278335; called by muse, mutect2, varscan2
- ALPP | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.821); catalogued as rs750382140, COSV67397766; called by muse, mutect2, varscan2
- ANAPC1 | c.4799G>A p.R1600Q | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs371127987; called by muse, varscan2
- ANK2 | c.8529C>A p.S2843R | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.034); catalogued as COSV52152709, COSV52181347; called by muse, mutect2, varscan2
- ANKFY1 | c.2333C>T p.A778V (on ENST00000341657 / NM_001330063.2; = p.A779V on NM_016376.5) | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV100493042; called by muse, mutect2, varscan2
- ANKRD27 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs377510221; called by muse, mutect2, varscan2
- ANKS1B | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100247242; called by muse, mutect2, varscan2
- ANXA7 | c.1075A>T p.T359S (on ENST00000372919 / NM_001320880.2; = p.T337S on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873485; called by muse, varscan2
- AP2M1 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99490851; called by muse, mutect2, varscan2
- APBB1IP | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs963182903, COSV63076147, COSV63076150; called by muse, mutect2, varscan2
- APLP1 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs775793591, COSV99697843; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARHGAP18 | c.1202G>A p.S401N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV100936244; called by muse, mutect2, varscan2
- ARHGAP27 | c.2618A>C p.Q873P (on ENST00000428638 / NM_001282290.1; = p.Q532P on NM_199282.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100976588; called by muse, mutect2, varscan2
- ARHGEF2 | c.2722C>T p.R908C (on ENST00000361247 / NM_001162383.2; = p.R880C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1355066378, COSV100561029; called by muse, mutect2, varscan2
- ARL8A | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99693366; called by muse, mutect2, varscan2
- ARMCX6 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV100726249; called by muse, mutect2
- ASB2 | c.1129T>C p.Y377H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60110747; called by muse, mutect2, varscan2
- ASCC2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745399329, COSV100316436; called by muse, mutect2, varscan2
- ASH1L | c.2134del p.R712Efs*23 | Frame Shift Del (DEL) | VAF 78/249 reads (31%) | catalogued as rs1558150870; called by mutect2, varscan2
- ASH2L | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99167031; called by muse, mutect2, varscan2
- ATG2A | c.3527T>A p.L1176Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101034692; called by muse, mutect2
- ATP11C | c.71_72del p.T24Sfs*21 | Frame Shift Del (DEL) | VAF 179/838 reads (21%) | catalogued as rs1224866423; called by pindel, varscan2
- ATP6V0D1 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs747711094, COSV52098856; called by muse, mutect2, varscan2
- ATP6V0D1 | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.992); catalogued as rs755703812, COSV99341284; called by muse, mutect2
- ATP6V1B1 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.608); catalogued as rs782166295, COSV52267950; called by muse, mutect2, varscan2
- ATP8B1 | c.3595C>T p.R1199C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs760353602, COSV52178896; called by muse, mutect2, varscan2
- ATRN | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs745613830, COSV99497670; called by muse, mutect2, varscan2
- ATXN1 | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV99787361; called by muse, mutect2, varscan2
- AUTS2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.992); catalogued as rs1383668832, COSV61381187; called by muse, mutect2, varscan2
- AXL | c.1439G>A p.R480H (on ENST00000301178 / NM_021913.5; = p.R471H on NM_001699.6) | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs751855310, COSV56572429; called by muse, mutect2, varscan2
- B3GALT1 | c.307del p.D103Mfs*10 | Frame Shift Del (DEL) | VAF 46/163 reads (28%) | catalogued as rs767927493, COSV100003016; called by mutect2, pindel, varscan2
- B4GALT3 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748981503, COSV60527699; called by muse, mutect2, varscan2
- BAHD1 | c.1292del p.P431Lfs*16 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as COSV69084708; called by mutect2, pindel, varscan2
- BCL2L15 | c.58A>G p.M20V | Missense Mutation (SNP) | VAF 486/1961 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1294548603, COSV100851594; called by mutect2, varscan2
- BCL7A | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 52/162 reads (32%) | catalogued as COSV55847466, COSV55850355; called by muse, mutect2, varscan2
- BCL7C | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768400764, COSV53062863, COSV99288737; called by muse, mutect2, varscan2
- BCL7C | c.358del p.Q120Sfs*33 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs758526156; called by mutect2, pindel, varscan2
- BEND2 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 345/1345 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs546359357, COSV66215101; called by muse, mutect2, varscan2
- BEST2 | c.1081C>A p.Q361K | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV99244614; called by muse, mutect2, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 80/272 reads (29%) | catalogued as rs779566914, COSV58300788; called by mutect2, varscan2
- BMPR2 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770128128, COSV65808758; called by muse, mutect2, varscan2
- BRD9 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs144680205; called by mutect2, varscan2
- C11orf80 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 41/109 reads (38%) | catalogued as COSV100691052; called by muse, mutect2, varscan2
- C19orf57 | c.1882del p.D628Tfs*45 (on ENST00000586783 / NM_001345843.1; = p.D597Tfs*45 on NM_024323.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 36/140 reads (26%) | catalogued as COSV59249941; called by mutect2, pindel, varscan2
- C1GALT1C1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1261355656, COSV100485635; called by muse, mutect2, varscan2
- C1RL | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs957812942; called by muse, varscan2
- C5 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 46/133 reads (35%) | catalogued as COSV99798482; called by muse, mutect2, varscan2
- C5AR1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as rs1198210885, COSV61892573; called by muse, mutect2, varscan2
- CACNA1C | c.6409G>A p.A2137T (on ENST00000399634 / NM_001167625.1; = p.A2066T on NM_000719.7) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100221325; called by muse, mutect2, varscan2
- CACNA1G | c.4288G>A p.G1430R | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61735111; called by muse, mutect2, varscan2
- CACNA1S | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs753195502, COSV62939709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB2 | c.1880G>A p.R627H (on ENST00000324631 / NM_201596.3; = p.R572H on NM_000724.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.992); catalogued as rs758934103, COSV56627222; called by muse, mutect2, varscan2
- CAD | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as rs1442684373, COSV99255527; called by muse, mutect2
- CALML5 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1482623360, COSV66702680; called by muse, mutect2, varscan2
- CAMSAP2 | c.1199G>A p.R400H (on ENST00000236925 / NM_001297707.2; = p.R389H on NM_203459.3) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as rs373510531; called by muse, mutect2, varscan2
- CAPN11 | c.1231C>A p.H411N | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV101291932; called by muse, mutect2, varscan2
- CARD9 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1011068857, COSV100261350; called by muse, mutect2, varscan2
- CASP9 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748271106, COSV100423775; called by muse, mutect2, varscan2
- CATSPERB | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 230/947 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs145060222; called by muse, mutect2, varscan2
- CBLN1 | c.384+2T>C p.X128_splice | Splice Site (SNP) | VAF 30/104 reads (29%) | catalogued as COSV99535775; called by muse, mutect2, varscan2
- CC2D1A | c.2813G>T p.R938M | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99582997; called by muse, mutect2, varscan2
- CCDC150 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV99777279; called by muse, mutect2, varscan2
- CCDC158 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 11/190 reads (6%) | catalogued as rs1165176101, COSV101187339; called by muse, mutect2
- CCDC22 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 215/704 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100879867; called by muse, mutect2, varscan2
- CCDC97 | c.331T>G p.F111V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV54191911; called by muse, mutect2, varscan2
- CCL14 | c.143G>A p.R48Q (on ENST00000618404 / NM_032963.4; = p.R64Q on NM_032962.4) | Missense Mutation (SNP) | VAF 17/491 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs201876342; called by muse, mutect2
- CCNE1 | c.319del p.V107Yfs*2 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as COSV99070422; called by mutect2, pindel, varscan2
- CCNE1 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs147896943; called by muse, mutect2, varscan2
- CCNT2 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99751053; called by muse, mutect2, varscan2
- CCNYL1 | c.807-1G>T p.X269_splice (on ENST00000295414 / NM_001330218.2; = p.X199_splice on NM_152523.2) | Splice Site (SNP) | VAF 110/474 reads (23%) | catalogued as COSV99776027; called by muse, mutect2, varscan2
- CD163L1 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58011187; called by muse, mutect2, varscan2
- CD55 | c.707T>A p.I236N | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100132610; called by muse, mutect2, varscan2
- CDC42BPG | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1424452327, COSV61349164; called by muse, mutect2, varscan2
- CDC42SE1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 88/390 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.866); catalogued as COSV100603389; called by mutect2, varscan2
- CDK11B | c.1417_1419del p.K473del | In Frame Del (DEL) | VAF 30/116 reads (26%) | catalogued as rs1557662466; called by mutect2, varscan2
- CDYL2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.433); catalogued as rs1434183748, COSV73654313; called by mutect2, varscan2
- CEP192 | c.2800C>T p.Q934* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100381857; called by muse, mutect2, varscan2
- CEP192 | c.7390C>T p.R2464* | Nonsense Mutation (SNP) | VAF 94/278 reads (34%) | catalogued as rs781480656, COSV58069822; called by muse, mutect2, varscan2
- CEP63 | c.961T>C p.Y321H | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100133025; called by muse, mutect2, varscan2
- CFAP65 | c.2519G>A p.C840Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100445697; called by muse, mutect2, varscan2
- CFL1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.237); catalogued as COSV100354147; called by muse, mutect2, varscan2
- CHD2 | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 138/1760 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs370737593; called by muse, mutect2
- CHD8 | c.7496C>A p.P2499H (on ENST00000646647 / NM_001170629.2; = p.P2220H on NM_020920.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1212151127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHERP | c.525C>T p.A175= | Splice Region (SNP) | VAF 11/35 reads (31%) | catalogued as rs979592645, COSV99550449; called by muse, mutect2, varscan2
- CHRM1 | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100186277; called by muse, mutect2, varscan2
- CHRNA2 | c.1253A>T p.E418V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1453727330, COSV53556180; called by muse, mutect2, varscan2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 57/234 reads (24%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CIAO2A | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 83/380 reads (22%) | catalogued as rs1056284662, COSV55538083; called by muse, mutect2, varscan2
- CIZ1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs370598569; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as rs752250702; called by mutect2, varscan2
- CKAP5 | c.4994T>C p.I1665T (on ENST00000529230 / NM_001008938.4; = p.I1605T on NM_014756.3) | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100371239; called by muse, mutect2, varscan2
- CKM | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs1803285, COSV99675486; called by muse, mutect2, varscan2
- CLCN5 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 182/585 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1557194734, COSV100260341; called by muse, mutect2, varscan2
- CLCN6 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 157/221 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1272214705, COSV100412131; called by muse, mutect2, varscan2
- CLCN6 | c.2581C>T p.R861W | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs376481714; called by muse, mutect2, varscan2
- CLCN7 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99247561; called by muse, mutect2, varscan2
- CLEC18B | c.448del p.Y150Tfs*26 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as COSV60578494; called by mutect2, varscan2
- CLIC6 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs996635682, COSV100659314; called by muse, mutect2
- CLTC | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV52251586; called by muse, mutect2, varscan2
- CLTCL1 | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1555953364, COSV54227228; called by muse, mutect2, varscan2
- CNGB1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs369288085; called by muse, mutect2, varscan2
- CNTN6 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100611595; called by muse, mutect2, varscan2
- COG3 | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100596699; called by muse, mutect2, varscan2
- COG4 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs376657474; called by muse, mutect2, varscan2
- COL14A1 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs373287048; called by muse, mutect2
- COL1A2 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs543810166, COSV99800672; called by muse, mutect2, varscan2
- COL5A2 | c.4412G>A p.R1471H | Missense Mutation (SNP) | VAF 92/326 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs781760462, COSV100880120, COSV100880657; called by muse, mutect2, varscan2
- COL7A1 | c.2104G>A p.V702I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV100097238; called by muse, mutect2, varscan2
- COP1 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 152/667 reads (23%) | catalogued as COSV100443751, COSV58173499; called by muse, mutect2, varscan2
- COQ8B | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 34/101 reads (34%) | catalogued as rs368669658, COSV53284675; called by muse, mutect2, varscan2
- CPA4 | c.713G>A p.W238* | Nonsense Mutation (SNP) | VAF 66/319 reads (21%) | catalogued as rs1013768494, COSV99745260; called by muse, mutect2, varscan2
- CREBBP | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.518); catalogued as rs1390790733, COSV52140506; called by muse, mutect2, varscan2
- CRKL | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1444326760, COSV62882831; called by muse, mutect2, varscan2
- CRYBA4 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as rs749066010, COSV61321943; called by muse, mutect2, varscan2
- CRYBB1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1000106932, COSV53232788, COSV99316145; called by muse, mutect2, varscan2
- CRYBB1 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as rs759541633, COSV53233884; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CRYGB | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs545870578, COSV53681007; called by muse, mutect2, varscan2
- CSPG4 | c.6547C>T p.R2183W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1291027438, COSV57892465, COSV57892994; called by muse, mutect2, varscan2
- CSPG4 | c.4992dup p.E1665Rfs*8 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | catalogued as rs757248830; called by mutect2, pindel
- CTNND2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1131691357, COSV58913955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL5 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs769598770, COSV101263733; called by muse, mutect2, varscan2
- CXCL11 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 99/325 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100134945; called by muse, mutect2, varscan2
- CYP19A1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 122/489 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs577716822, COSV53061299; called by muse, mutect2, varscan2
- CYP1B1 | c.868del p.R290Afs*3 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as COSV99037570; called by mutect2, pindel, varscan2
- CYP27B1 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99141627; called by muse, mutect2
- CYP27C1 | c.1086del p.I364Sfs*14 | Frame Shift Del (DEL) | VAF 61/257 reads (24%) | catalogued as rs767024106; called by mutect2, pindel, varscan2
- CYP2R1 | c.122del p.P41Rfs*26 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs1205847900; called by mutect2, varscan2
- CYP3A43 | c.1000_1002del p.E334del | In Frame Del (DEL) | VAF 14/116 reads (12%) | catalogued as rs962572944; called by pindel, varscan2
- CYP51A1 | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as COSV99134056; called by muse, varscan2
- DAG1 | c.1708G>A p.V570M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as rs370669533, COSV58184496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF11 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs762891063, COSV58108975; called by muse, mutect2, varscan2
- DCHS1 | c.4814G>T p.R1605L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV100202446; called by muse, mutect2, varscan2
- DCSTAMP | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 40/1096 reads (4%) | catalogued as rs200311973, COSV52576874; called by muse, mutect2
- DDI1 | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100160331; called by muse, mutect2, varscan2
- DDR2 | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV100906788, COSV63373314; called by muse, mutect2, varscan2
- DDX50 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV101007297; called by muse, mutect2, varscan2
- DENND6A | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771772317, COSV60767638, COSV60767952; called by muse, mutect2, varscan2
- DERA | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 83/313 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760703237, COSV101397336; called by muse, mutect2, varscan2
- DHODH | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs762591793, COSV99536976; called by muse, mutect2, varscan2
- DIDO1 | c.1169A>C p.E390A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV99826721; called by muse, mutect2, varscan2
- DISC1 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs376617666; called by muse, mutect2, varscan2
- DLD | c.1344_1347del p.D448Efs*16 | Frame Shift Del (DEL) | VAF 48/222 reads (22%) | catalogued as rs1402761530; called by pindel, varscan2
- DMRT1 | c.824T>C p.M275T | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV101206702; called by muse, mutect2, varscan2
- DNAH1 | c.3617A>C p.N1206T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV70233919; called by muse, mutect2, varscan2
- DNAH12 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1284194690, COSV100244716; called by muse, mutect2, varscan2
- DNAH3 | c.8957G>A p.R2986Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.116); catalogued as rs764888018, COSV99766194; called by muse, mutect2, varscan2
- DNAH3 | c.8804G>A p.R2935Q | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs369073466; called by muse, mutect2, varscan2
- DNAJC24 | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 204/795 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs181756989, COSV99541242; called by muse, mutect2, varscan2
- DNASE1L3 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755495435, COSV100568806; called by muse, mutect2, varscan2
- DNM1L | c.1689C>G p.S563R | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99846353; called by muse, mutect2, varscan2
- DNM2 | c.2156G>A p.R719Q (on ENST00000355667 / NM_001005360.3; = p.R715Q on NM_004945.3) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1181350787, COSV99284252; called by muse, mutect2, varscan2
- DNMT1 | c.1660G>C p.A554P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532505, COSV100532901; called by muse, mutect2, varscan2
- DNTTIP2 | c.274T>C p.S92P | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100785200; called by muse, mutect2, varscan2
- DOCK10 | c.521del p.G174Vfs*24 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as rs746265647, COSV99288335; called by mutect2, pindel, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 57/120 reads (48%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.4713dup p.T1572Yfs*10 | Frame Shift Ins (INS) | VAF 48/176 reads (27%) | catalogued as rs745668075; called by mutect2, varscan2
- DOCK5 | c.5137G>A p.A1713T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV99377485; called by muse, mutect2, varscan2
- DPYSL2 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1334281681, COSV100234094; called by muse, mutect2, varscan2
- DRC7 | c.1409-1G>T p.X470_splice | Splice Site (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100395852; called by muse, mutect2, varscan2
- DSG3 | c.2762C>A p.S921Y | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV57129554, COSV99934576; called by muse, mutect2, varscan2
- DVL2 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs926078603, COSV99138751; called by muse, mutect2, varscan2
- DYDC1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs1247521194, COSV100943842; called by muse, mutect2, varscan2
- DYNC2H1 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 118/412 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs745436653, COSV100519421; called by muse, varscan2
- DYNC2H1 | c.7276C>T p.R2426C | Missense Mutation (SNP) | VAF 134/527 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs755651498, COSV100519423; called by muse, mutect2, varscan2
- DYRK3 | c.1259G>A p.C420Y | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs947498467, COSV100895795; called by muse, mutect2, varscan2
- DYSF | c.3597G>T p.W1199C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50524491, COSV99249728; called by muse, mutect2
- EEF1AKNMT | c.1967C>T p.P656L (on ENST00000361735 / NM_015935.5; = p.P570L on NM_014955.3) | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100675992; called by muse, mutect2, varscan2
- EEF2 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778505808, COSV100500915; called by muse, varscan2
- EEF2K | c.586del p.E196Rfs*22 | Frame Shift Del (DEL) | VAF 43/169 reads (25%) | catalogued as rs1567276794; called by mutect2, pindel, varscan2
- EEFSEC | c.1169A>G p.D390G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99631048; called by muse, mutect2, varscan2
- EFEMP2 | c.166_168del p.N56del | In Frame Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs1382119098; called by mutect2, pindel, varscan2
- EFHC2 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101375514; called by muse, mutect2, varscan2
- EGR1 | c.450G>A p.W150* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99525560; called by muse, mutect2, varscan2
- EGR3 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.163); catalogued as COSV100416253; called by muse, mutect2, varscan2
- EIF2A | c.498T>A p.H166Q | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as COSV99856079; called by muse, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 78/308 reads (25%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF3J | c.596T>A p.I199N | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99969294; called by muse, mutect2, varscan2
- EMC1 | c.2376+2T>G p.X792_splice | Splice Site (SNP) | VAF 72/399 reads (18%) | catalogued as COSV100916465; called by muse, mutect2, varscan2
- EME1 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99869083; called by muse, mutect2, varscan2
- EP300 | c.3653A>G p.D1218G | Missense Mutation (SNP) | VAF 104/493 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99609486; called by muse, mutect2, varscan2
- EPB41L3 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 127/537 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59450932; called by muse, mutect2, varscan2
- EPB41L3 | c.897T>A p.D299E | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100549958; called by muse, mutect2, varscan2
- EPHB6 | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101235992; called by muse, mutect2, varscan2
- EPM2AIP1 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV51618120; called by muse, mutect2, varscan2
- EPN3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141972412; called by muse, mutect2, varscan2
- ERF | c.502T>C p.S168P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.763); catalogued as COSV99724799; called by muse, mutect2, varscan2
- ESX1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs868909391, COSV101006492; called by muse, mutect2, varscan2
- EVX2 | c.172dup p.L58Pfs*54 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs759607919; called by mutect2, pindel, varscan2
- EXOC6 | c.411T>C p.P137= | Splice Region (SNP) | VAF 81/277 reads (29%) | catalogued as COSV99592344; called by muse, mutect2, varscan2
- EXPH5 | c.5279C>A p.P1760H | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV99762024; called by muse, mutect2, varscan2
- EYA3 | c.159T>C p.I53= | Splice Region (SNP) | VAF 45/214 reads (21%) | catalogued as COSV100870282; called by muse, mutect2, varscan2
- F5 | c.4310C>T p.T1437I | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV100889200; called by muse, mutect2, varscan2
- FAM163A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100523131; called by muse, mutect2
- FAM183A | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 95/318 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100088408; called by muse, mutect2, varscan2
- FAM199X | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100245561; called by muse, mutect2, varscan2
- FAM71C | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs753279689, COSV60942561; called by muse, mutect2, varscan2
- FAM83G | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.171); catalogued as COSV100525411; called by muse, mutect2, varscan2
- FARP1 | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 105/470 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757781772, COSV60332052; called by muse, mutect2, varscan2
- FAT4 | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.959); catalogued as COSV101272595; called by muse, mutect2, varscan2
- FBXL14 | c.884A>C p.Q295P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV100201594; called by muse, mutect2, varscan2
- FBXL19 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.979); catalogued as COSV100609276; called by mutect2, varscan2
- FBXL7 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs1256940003, COSV61654334; called by muse, mutect2, varscan2
- FBXO10 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 129/506 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.316); catalogued as rs1185836755, COSV99447095; called by muse, mutect2, varscan2
- FCGBP | c.8189C>G p.P2730R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99663540; called by muse, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FKBP6 | c.666_668del p.L223del | In Frame Del (DEL) | VAF 38/207 reads (18%) | catalogued as rs1476511450; called by mutect2, pindel, varscan2
- FLCN | c.751T>A p.W251R | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99550632; called by muse, mutect2, varscan2
- FLG | c.9331C>T p.R3111C | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1345385203, COSV64245493; called by muse, mutect2, varscan2
- FLG2 | c.2849A>G p.Q950R | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.514); catalogued as rs1288308098, COSV101166091; called by muse, mutect2, varscan2
- FLNB | c.4150A>G p.S1384G | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99914299; called by muse, mutect2, varscan2
- FLNC | c.3866C>T p.T1289M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs755896234, COSV57968713; called by muse, mutect2, varscan2
- FLT1 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs201044311, COSV56717528; called by muse, mutect2, varscan2
- FNDC1 | c.3805G>A p.V1269M | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV99796422; called by muse, mutect2, varscan2
- FNDC3A | c.845T>C p.V282A (on ENST00000492622 / NM_001079673.2; = p.V226A on NM_014923.5) | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV101001340; called by muse, mutect2, varscan2
- FOLR1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as rs764420714, COSV100398575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRAS1 | c.4649T>C p.L1550P | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV99354901; called by muse, mutect2
- FREM1 | c.1637G>T p.R546L | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101085194, COSV66523642; called by muse, mutect2, varscan2
- FRMPD1 | c.4718G>A p.R1573Q | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs757877299, COSV66700145; called by muse, mutect2, varscan2
- FRRS1L | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV101643933; called by mutect2, varscan2
- FSCN3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 102/454 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs148605578; called by muse, mutect2, varscan2
- FSD1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1189253379, COSV99696962; called by muse, mutect2, varscan2
- FTO | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 146/557 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs761330347, COSV99061594; called by muse, mutect2, varscan2
- GAB4 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as rs1380351237, COSV68753940; called by muse, mutect2, varscan2
- GABBR1 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs761586998, COSV100589945; called by muse, mutect2, varscan2
- GABPB2 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs370629015; called by muse, mutect2, varscan2
- GABRQ | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 222/767 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1343935503, COSV100941393; called by muse, varscan2
- GABRQ | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782699208, COSV64782303; called by muse, mutect2, varscan2
- GALNT16 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs984809988, COSV61886238; called by muse, mutect2, varscan2
- GALNTL6 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 66/1547 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs774850813, COSV101560416; called by muse, mutect2
- GALT | c.550del p.H184Tfs*35 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as COSV66593417; called by mutect2, pindel, varscan2
- GASK1B | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs376041501; called by muse, varscan2
- GBP1 | c.1391A>G p.Y464C | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1283925952, COSV100976292; called by muse, varscan2
- GCFC2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 94/393 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs373951174, COSV58082874; called by muse, mutect2, varscan2
- GCHFR | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV53066628; called by muse, mutect2, varscan2
- GCLC | c.761T>C p.V254A (on ENST00000643939; = p.V252A on NM_001498.4) | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV99988844; called by muse, mutect2, varscan2
- GDF2 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs372529223; called by muse, mutect2, varscan2
- GDPD5 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as rs377131289; called by muse, mutect2, varscan2
- GGA2 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as rs751749491, COSV100564810; called by muse, mutect2, varscan2
- GGA3 | c.1711G>T p.G571C (on ENST00000537686 / NM_138619.4; = p.G538C on NM_014001.5) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99822271; called by muse, mutect2, varscan2
- GIGYF2 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as COSV101004575; called by muse, mutect2, varscan2
- GIMAP8 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100217641; called by muse, mutect2, varscan2
- GKN1 | c.481del p.Y161Tfs*38 | Frame Shift Del (DEL) | VAF 143/486 reads (29%) | catalogued as rs759880395; called by mutect2, pindel, varscan2
- GLB1L2 | c.354-1G>T p.X118_splice | Splice Site (SNP) | VAF 45/482 reads (9%) | catalogued as COSV100335336; called by muse, mutect2
- GLP1R | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs150253529; called by muse, mutect2, varscan2
- GNA14 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs545966792, COSV100503311; called by muse, mutect2, varscan2
- GNB1L | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV100284331; called by muse, mutect2, varscan2
- GNB5 | c.1105C>T p.R369C (on ENST00000261837 / NM_016194.4; = p.R327C on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759589203, COSV99953573; called by muse, mutect2, varscan2
- GOLGA1 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 251/1041 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1259269932, COSV101001991; called by muse, mutect2, varscan2
- GOLGA2 | c.2564A>G p.Y855C | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100360234; called by muse, mutect2
- GOLGA4 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372845682; called by muse, mutect2, varscan2
- GON4L | c.2866C>A p.L956I | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV99675347; called by muse, mutect2, varscan2
- GOT1L1 | c.1217A>G p.E406G | Missense Mutation (SNP) | VAF 199/682 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100294647; called by muse, varscan2
- GPAA1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs1160454730, COSV100284176; called by muse, mutect2, varscan2
- GPC4 | c.970A>G p.M324V | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.479); catalogued as COSV100895574; called by muse, mutect2, varscan2
- GPC6 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1463269575, COSV100989700; called by muse, mutect2, varscan2
- GPHN | c.1863C>G p.I621M (on ENST00000315266 / NM_001377519.1; = p.I654M on NM_020806.5) | Missense Mutation (SNP) | VAF 159/764 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs750415918, COSV100017303, COSV59486664; called by muse, mutect2, varscan2
- GPR12 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs369035674; called by muse, varscan2
- GPR141 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 264/1274 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.623); catalogued as COSV100550404; called by muse, varscan2
- GPR173 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1556806049, COSV60238960; called by muse, mutect2, varscan2
- GPR85 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); catalogued as rs372071765; called by muse, mutect2, varscan2
- GPRC5B | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100315246; called by muse, mutect2, varscan2
- GRAMD2B | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99587230; called by muse, mutect2, varscan2
- GRIA4 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1366635703, COSV99233721; called by muse, mutect2, varscan2
- GRIPAP1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 387/1550 reads (25%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as rs1464612429, COSV100904359; called by muse, mutect2, varscan2
- GRM3 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.538); catalogued as rs563221454, COSV100862145, COSV64470856; called by muse, mutect2, varscan2
- GSPT2 | c.549del p.E184Rfs*3 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | catalogued as COSV61215381; called by mutect2, pindel, varscan2
- GTF2B | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as rs769046476, COSV100980563; called by muse, mutect2, varscan2
- GTF2I | c.566del p.L189* | Frame Shift Del (DEL) | VAF 116/635 reads (18%) | catalogued as COSV60399209; called by mutect2, pindel, varscan2
- GTF2IRD2 | c.1815del p.F606Sfs*8 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs1554416448; called by mutect2, varscan2
- GTPBP3 | c.944A>T p.E315V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50193973; called by muse, mutect2, varscan2
- GYS1 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as rs1338075033, COSV54401846, COSV99621061; called by muse, mutect2, varscan2
- GZMH | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.16); catalogued as rs766652570, COSV53537686; called by muse, mutect2, varscan2
- H4C7 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55099622, COSV55099671; called by muse, mutect2, varscan2
- H6PD | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149081812; called by muse, mutect2, varscan2
- HAVCR1 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1213609330, COSV100208185; called by muse, mutect2
- HCN4 | c.3371del p.G1124Vfs*57 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1255143771; called by mutect2, pindel, varscan2
- HEBP1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as rs759302892, COSV50009387; called by muse, mutect2, varscan2
- HECA | c.1124G>A p.G375D | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100866245; called by muse, mutect2, varscan2
- HECTD1 | c.3763G>A p.A1255T | Missense Mutation (SNP) | VAF 215/719 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV101237467; called by muse, mutect2, varscan2
- HERC4 | c.2320A>G p.R774G (on ENST00000395198 / NM_022079.3; = p.R766G on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV99517345; called by muse, mutect2, varscan2
- HEXB | c.1417+2T>C p.X473_splice | Splice Site (SNP) | VAF 403/1578 reads (26%) | catalogued as COSV99714605; called by muse, mutect2, varscan2
- HHATL | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100124583; called by muse, mutect2
- HID1 | c.2042C>T p.T681M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs115082567, COSV100172985; called by muse, mutect2, varscan2
- HIF3A | c.1160G>A p.R387Q (on ENST00000377670 / NM_152795.4; = p.R318Q on NM_022462.4) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs770922602, COSV99356012; called by muse, mutect2, varscan2
- HIVEP2 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99175008; called by muse, mutect2, varscan2
- HIVEP3 | c.5245C>T p.R1749C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776982758, COSV99913595; called by muse, mutect2, varscan2
- HK1 | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs775763125, COSV53864055; called by muse, mutect2
- HKDC1 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as rs780647583, COSV63576887; called by muse, mutect2, varscan2
- HLA-A | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs772821446, COSV100954632; called by muse, varscan2
- HLA-F | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.505); catalogued as rs764964427, COSV99466301; called by muse, varscan2
- HOXA7 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361050955, COSV99636687; called by muse, mutect2, varscan2
- HOXB3 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV61144708; called by muse, mutect2, varscan2
- HSD17B14 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV54415299, COSV99622922; called by muse, mutect2, varscan2
- HSDL1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs199812312, COSV99550359; called by muse, mutect2, varscan2
- HSH2D | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.683); catalogued as rs531173054, COSV53737725; called by muse, mutect2, varscan2
- HSPA8 | c.182T>C p.M61T | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as rs1252070613, COSV99914553; called by muse, varscan2
- HSPA9 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99785629; called by muse, mutect2, varscan2
- HSPG2 | c.6583C>T p.R2195W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs566319401, COSV65971546; called by muse, mutect2, varscan2
- HSPG2 | c.2879G>A p.S960N | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768568677, COSV101021034; called by muse, mutect2, varscan2
- HTR5A | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV55280543; called by muse, mutect2, varscan2
- HYKK | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1022640002, COSV101195099; called by muse, mutect2, varscan2
- ID1 | c.354del p.G120Afs*20 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as COSV65888960; called by mutect2, pindel
- IDH3G | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs782789248, COSV99473144, COSV99473452; called by muse, mutect2, varscan2
- IFNGR1 | c.1121T>G p.I374R | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100880933; called by muse, mutect2, varscan2
- IGDCC4 | c.2434G>A p.G812S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs368140698; called by muse, mutect2, varscan2
- IL18R1 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as rs35292939; called by muse, mutect2, varscan2
- IL4R | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376032165; called by muse, mutect2, varscan2
- IMMP2L | c.263A>C p.K88T | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV100072566; called by muse, mutect2, varscan2
- IMMP2L | c.156del p.S53Afs*9 | Frame Shift Del (DEL) | VAF 23/129 reads (18%) | catalogued as rs764675061; called by mutect2, pindel, varscan2
- IMPA1 | c.303-2dup p.X101_splice | Splice Site (INS) | VAF 16/46 reads (35%) | catalogued as rs763126450; called by mutect2, varscan2
- INTS2 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.679); catalogued as COSV99248611; called by muse, mutect2, varscan2
- IP6K3 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); catalogued as rs145073660; called by muse, mutect2, varscan2
- IPO8 | c.2513T>C p.I838T | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV99805571; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1269G>T p.E423D (on ENST00000485419 / NM_001197113.1; = p.E347D on NM_014575.3) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as COSV100541714, COSV61839004; called by muse, varscan2
- IQSEC2 | c.2753T>C p.V918A (on ENST00000642864 / NM_001111125.3; = p.V713A on NM_015075.2) | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100945044; called by muse, mutect2, varscan2
- IRAG2 | c.2975C>T p.S992L (on ENST00000636465; = p.S37L on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs753672679, COSV63140686; called by muse, mutect2, varscan2
- ITGA7 | c.2060G>A p.C687Y (on ENST00000555728; = p.C643Y on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748345970, COSV99151329; called by mutect2, varscan2
- ITGB2 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs1053155608, COSV100186060; called by muse, mutect2, varscan2
- ITIH5 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs1247790056, COSV56906234; called by muse, mutect2, varscan2
- JAK3 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | catalogued as rs1198251679, CM012988, COSV101512995; called by muse, mutect2, varscan2
- JAK3 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs587778414, COSV71685771; ClinVar: not provided; called by muse, mutect2, varscan2
- JAKMIP1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs371853673, COSV51537918; called by muse, mutect2, varscan2
- JAML | c.424+2T>C p.X142_splice (on ENST00000356289 / NM_001098526.2; = p.X132_splice on NM_153206.3) | Splice Site (SNP) | VAF 52/164 reads (32%) | catalogued as COSV99409679; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.199T>C p.W67R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100584135; called by mutect2, varscan2
- JPH3 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99413816; called by muse, mutect2, varscan2
- KATNA1 | c.1403del p.K468Rfs*39 | Frame Shift Del (DEL) | VAF 97/325 reads (30%) | catalogued as COSV59502594; called by mutect2, pindel, varscan2
- KCNA10 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs200254580, COSV63904564; called by muse, mutect2, varscan2
- KCNA2 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60369761; called by muse, mutect2, varscan2
- KCNC2 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 221/806 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs199735865, COSV54374815; called by muse, mutect2, varscan2
- KCND3 | c.1076G>A p.W359* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100138151; called by muse, mutect2, varscan2
- KCNK13 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs536825700, COSV56411462; called by muse, mutect2, varscan2
- KCNQ2 | c.1267G>T p.G423W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV100610450; called by muse, mutect2, varscan2
- KCNT2 | c.1997+2T>C p.X666_splice | Splice Site (SNP) | VAF 152/513 reads (30%) | catalogued as COSV99655852; called by muse, mutect2, varscan2
- KCTD15 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1361909192, COSV99393313; called by muse, mutect2
- KDM1A | c.2484G>T p.Q828H | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.529); catalogued as COSV100174107; called by muse, mutect2
- KDM2B | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 123/456 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555311243, COSV65637893; called by muse, mutect2, varscan2
- KDM5B | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs758565397, COSV52508294; called by muse, mutect2, varscan2
- KHNYN | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs774598219, COSV99249998; called by muse, mutect2, varscan2
- KIAA0319L | c.2171T>C p.V724A | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.279); catalogued as COSV100357614; called by muse, mutect2, varscan2
- KIAA1210 | c.1782G>T p.M594I | Missense Mutation (SNP) | VAF 187/717 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV101274350; called by muse, mutect2, varscan2
- KIAA1217 | c.2926del p.R976Gfs*16 | Frame Shift Del (DEL) | VAF 40/134 reads (30%) | catalogued as rs1276999337, COSV56814085; called by mutect2, varscan2
- KIF1B | c.1855C>T p.R619C (on ENST00000377086 / NM_001365952.1; = p.R573C on NM_015074.3) | Missense Mutation (SNP) | VAF 92/380 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752648536, COSV55803056; ClinVar: uncertain significance; called by muse, varscan2
- KIF1B | c.2992G>C p.E998Q (on ENST00000377086 / NM_001365952.1; = p.E952Q on NM_015074.3) | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99823943; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLF11 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142970758; called by muse, mutect2, varscan2
- KLHL14 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 128/431 reads (30%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.921); catalogued as rs1410508719, COSV100809208; called by muse, mutect2, varscan2
- KLRK1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 184/647 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV99555227; called by muse, mutect2, varscan2
- KMO | c.478T>C p.C160R | Missense Mutation (SNP) | VAF 109/377 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.295); catalogued as COSV100844812; called by muse, mutect2, varscan2
- KRT18 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.396); catalogued as COSV66316539; called by muse, mutect2
- KRT24 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV99232131; called by muse, mutect2, varscan2
- KRT6C | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 77/301 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.434); catalogued as COSV99360147; called by muse, mutect2, varscan2
- KRT71 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs369905148; called by muse, mutect2, varscan2
- KRT85 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs768562539, COSV57738497; called by muse, mutect2, varscan2
- KRTAP10-7 | c.610T>C p.C204R | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1555928662, COSV100170278; called by muse, mutect2, varscan2
- KRTAP13-1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs763603199, COSV100819897, COSV62663095; called by muse, mutect2, varscan2
- KSR1 | c.565C>T p.R189W (on ENST00000644974 / NM_001367810.1; = p.R52W on NM_014238.2) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs759278857, COSV52030256; called by muse, mutect2, varscan2
- LAMB4 | c.4186G>T p.G1396C | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99225146; called by muse, mutect2, varscan2
- LAMP1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as rs757618803, COSV100208732; called by muse, mutect2, varscan2
- LARGE1 | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100506186, COSV61662816; called by muse, mutect2, varscan2
- LARP4B | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 51/244 reads (21%) | catalogued as COSV60220201; called by muse, mutect2, varscan2
- LCN9 | c.435del p.Y145* | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as COSV52992289; called by mutect2, pindel, varscan2
- LCOR | c.2672G>A p.R891H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs141178994; called by muse, mutect2, varscan2
- LCT | c.4922T>C p.V1641A | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs557029000, COSV99930176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LENG8 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs776967583, COSV58727638; called by muse, mutect2, varscan2
- LGALS3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV99582503; called by muse, mutect2, varscan2
- LIMK1 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs544200500, COSV100283376; called by muse, mutect2
- LMBRD2 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1432499396, COSV56952520; called by muse, mutect2, varscan2
- LONP1 | c.2756A>T p.D919V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100028679; called by muse, mutect2, varscan2
- LPAR4 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 50/732 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101425152; called by muse, mutect2
- LRFN3 | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99873537; called by muse, varscan2
- LRIT2 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs199853938; called by muse, mutect2, varscan2
- LRP1 | c.6152T>G p.I2051S | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99676782; called by muse, mutect2, varscan2
- LRP10 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760967418, COSV62077686; called by muse, mutect2, varscan2
- LRP2 | c.3909G>T p.K1303N | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.543); catalogued as COSV55556736, COSV99789777; called by muse, mutect2, varscan2
- LRP5 | c.3082G>A p.D1028N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1209062729, COSV53713453; called by muse, mutect2, varscan2
- LSG1 | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54570706; called by muse, mutect2, varscan2
- LTN1 | c.1239del p.F413Lfs*7 | Frame Shift Del (DEL) | VAF 69/319 reads (22%) | catalogued as rs1568851261; called by mutect2, pindel, varscan2
- LY6E | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV52870171; called by muse, mutect2
- LYST | c.4844T>C p.I1615T | Missense Mutation (SNP) | VAF 188/723 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as rs1431781727, COSV101090085; called by muse, mutect2, varscan2
- MACO1 | c.306dup p.A103Cfs*3 | Frame Shift Ins (INS) | VAF 70/309 reads (23%) | catalogued as rs752439249; called by mutect2, varscan2
- MADD | c.3249G>T p.M1083I | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV100211853; called by muse, varscan2
- MALT1 | c.1475C>T p.T492M | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769025149, COSV100618825, COSV61936238; called by muse, mutect2, varscan2
- MALT1 | c.2134A>G p.I712V | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.072); catalogued as rs780283850, COSV100618827; called by muse, mutect2, varscan2
- MAN2C1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV99145706; called by muse, mutect2
- MAP1S | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs373990918; called by muse, mutect2, varscan2
- MAP3K6 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100539518; called by muse, mutect2
- MAPK4 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as rs764772500, COSV68541047, COSV68543116; called by muse, mutect2
- MAPK8 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs1402727389, COSV100827513; called by muse, mutect2, varscan2
- MARCHF7 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs139916486; called by muse, varscan2
- MARCKSL1 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV100269496, COSV61482189; called by muse, mutect2, varscan2
- MARK2 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs767626610, COSV100159048; called by muse, mutect2, varscan2
- MARK3 | c.2131G>A p.V711M (on ENST00000429436 / NM_001128918.3; = p.V687M on NM_002376.6) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748756539, COSV99358225, COSV99358612; called by muse, mutect2, varscan2
- MASP2 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1202236725, COSV99534412; called by muse, mutect2
- MBD2 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 281/1122 reads (25%) | catalogued as COSV56501621; called by muse, mutect2, varscan2
- MCCC1 | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV99659993; called by muse, mutect2, varscan2
- MCHR1 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs200156668, COSV50760931; called by muse, mutect2, varscan2
- MCM4 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768182076, COSV50634490; called by muse, mutect2, varscan2
- MDN1 | c.12425G>A p.R4142H | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753549140, COSV65526619; called by muse, mutect2, varscan2
- MDN1 | c.2893C>T p.R965W | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201577289; called by muse, mutect2, varscan2
- MED13 | c.103T>C p.W35R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101180701; called by muse, mutect2, varscan2
- MED8 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV99318479; called by muse, mutect2, varscan2
- MEGF10 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs377547826, COSV99175323; called by muse, mutect2, varscan2
- MEGF10 | c.2812A>C p.T938P | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99175331; called by muse, mutect2, varscan2
- MEGF8 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.874); catalogued as rs1270793237, COSV52074796; called by muse, varscan2
- MELTF | c.1878_1879insT p.V627Cfs*29 | Frame Shift Ins (INS) | VAF 13/91 reads (14%) | catalogued as COSV99586486; called by mutect2, pindel, varscan2
- MGAT1 | c.920A>C p.E307A | Missense Mutation (SNP) | VAF 8/17 reads (47%) | PolyPhen probably damaging (1); catalogued as COSV100286794; called by muse, mutect2, varscan2
- MGAT5B | c.1627del p.L543Wfs*71 (on ENST00000569840 / NM_001199172.2; = p.L541Wfs*71 on NM_144677.3) | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs778939334; called by mutect2, pindel, varscan2
- MIA2 | c.2162del p.P721Hfs*30 | Frame Shift Del (DEL) | VAF 55/244 reads (23%) | catalogued as rs780386330; called by mutect2, pindel, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs765803753; called by pindel, varscan2
- MIER3 | c.1052+1G>A p.X351_splice (on ENST00000381199 / NM_001297599.2; = p.X350_splice on NM_152622.4) | Splice Site (SNP) | VAF 11/55 reads (20%) | catalogued as COSV67082982; called by muse, mutect2, varscan2
- MIOX | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs564759857, COSV53314410, COSV53314572; called by muse, mutect2, varscan2
- MKX | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 197/558 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs904398076, COSV65391974; called by muse, mutect2, varscan2
- MLXIPL | c.2372T>C p.V791A | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100515152; called by mutect2, varscan2
- MMD2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780813727, COSV101287097; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | catalogued as rs755830405; called by mutect2, varscan2
- MOGAT1 | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV101490105; called by muse, varscan2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 88/279 reads (32%) | catalogued as rs756600463; called by mutect2, varscan2
- MRPL16 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1268442538, COSV100276180; called by muse, varscan2
- MRPS11 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as rs774896757, COSV100363794; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/212 reads (15%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MTFR2 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 147/447 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369622195; called by muse, mutect2, varscan2
- MTOR | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV63878091; called by muse, mutect2, varscan2
- MTPAP | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1163288473; called by muse, mutect2
- MTREX | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 23/581 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100044392; called by muse, mutect2
- MUC4 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV62129349; called by muse, mutect2, varscan2
- MUS81 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); catalogued as COSV100337359; called by muse, mutect2
- MYH4 | c.3071T>C p.L1024P | Missense Mutation (SNP) | VAF 117/368 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150138598; called by muse, mutect2, varscan2
- MYH9 | c.4306G>A p.A1436T | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs373912645, CM147352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK3 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.17); catalogued as rs758996855, COSV101189180; called by muse, mutect2, varscan2
- MYMK | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as rs750970882, COSV60601655; called by muse, mutect2, varscan2
- MYO9A | c.6385G>A p.V2129I | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs777780131, COSV100614081; called by muse, mutect2, varscan2
- MYOC | c.913A>G p.S305G | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.257); catalogued as COSV99231663; called by muse, mutect2, varscan2
- MYOM2 | c.2430G>A p.M810I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.127); catalogued as COSV100038114; called by muse, mutect2, varscan2
- MYOT | c.1366G>T p.V456F | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51799573, COSV99296573; called by muse, mutect2
- NACC1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs751983812, COSV52835502; called by muse, mutect2
- NAV3 | c.6944G>A p.R2315Q (on ENST00000397909 / NM_001024383.2; = p.R2293Q on NM_014903.6) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs552595814, COSV57078453, COSV57096626; called by muse, mutect2, varscan2
- NBEAL2 | c.7181G>A p.R2394Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs779645523, COSV52756347; called by muse, mutect2, varscan2
- NCAM1 | c.1814C>T p.T605M (on ENST00000316851 / NM_181351.5; = p.T595M on NM_000615.7) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782353037, COSV57517108; called by muse, mutect2, varscan2
- NCEH1 | c.1087C>T p.R363C (on ENST00000538775; = p.R323C on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs754711926, COSV56438285; called by muse, mutect2, varscan2
- NCOA5 | c.607A>G p.I203V | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV99275905; called by muse, mutect2, varscan2
- NDUFS1 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99261322; called by muse, mutect2, varscan2
- NEB | c.2783del p.P928Lfs*29 | Frame Shift Del (DEL) | VAF 136/455 reads (30%) | catalogued as rs751346602; called by mutect2, varscan2
- NECAB3 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772875114, COSV55775460; called by muse, mutect2
- NECTIN4 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as rs774621220, COSV100920011; called by muse, mutect2, varscan2
- NEDD9 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs1226283753, COSV65221469; called by muse, mutect2, varscan2
- NEK5 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs774379746, COSV100839283, COSV62881860; called by muse, mutect2, varscan2
- NEUROG2 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as COSV100511943; called by muse, mutect2, varscan2
- NEXMIF | c.3106A>G p.I1036V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99281519; called by muse, mutect2, varscan2
- NFATC4 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs939191955, COSV51613228; called by muse, mutect2, varscan2
- NFIC | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100545588; called by muse, mutect2, varscan2
- NIM1K | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 145/620 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs1238025717, COSV100390362; called by muse, mutect2, varscan2
- NIPBL | c.7936C>T p.R2646W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1308325504, COSV99242068; called by muse, mutect2, varscan2
- NLRC4 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV100707479; called by muse, mutect2
- NLRP13 | c.1787T>C p.I596T | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100738414; called by muse, mutect2, varscan2
- NLRP3 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 141/555 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs201867582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP8 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs759131290, COSV52587344; called by muse, mutect2, varscan2
- NME8 | c.1023A>T p.E341D | Missense Mutation (SNP) | VAF 17/596 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.208); catalogued as COSV99553689; called by muse, mutect2
- NMRK1 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 386/1332 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs773174854, COSV63112768; called by muse, mutect2, varscan2
- NOL6 | c.2965A>G p.M989V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as rs758465557, COSV53045310; called by muse, mutect2, varscan2
- NOTCH3 | c.6102del p.G2035Vfs*50 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs771517374; called by mutect2, pindel, varscan2
- NOVA1 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99948408; called by muse, mutect2, varscan2
- NPR2 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100439025; called by muse, mutect2, varscan2
- NR1D1 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs752175778, COSV99225740; called by muse, mutect2, varscan2
- NR1I2 | c.652del p.E218Rfs*59 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs1559790718; called by mutect2, varscan2
- NRSN1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 60/216 reads (28%) | catalogued as COSV101027348, COSV65894575; called by muse, mutect2, varscan2
- NSD1 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 113/441 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.118); catalogued as rs189716582, COSV100729697; called by muse, mutect2, varscan2
- NSDHL | c.889T>G p.Y297D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100938682; called by muse, mutect2, varscan2
- NTF3 | c.18G>A p.T6= | Splice Region (SNP) | VAF 19/84 reads (23%) | catalogued as rs746213486, COSV70433992; called by muse, mutect2, varscan2
- NTRK3 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs546426782, COSV100446296, COSV58125477; called by muse, mutect2, varscan2
- NUP88 | c.1936A>C p.S646R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV99336909; called by muse, mutect2, varscan2
- OAS3 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs199852899; called by muse, mutect2, varscan2
- OLA1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 138/388 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs1320025722, COSV99506679; called by muse, mutect2, varscan2
- OR10H1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV100612467; called by muse, mutect2, varscan2
- OR10J1 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs201898028, COSV101419954; called by muse, mutect2, varscan2
- OR13C3 | c.737del p.F246Sfs*13 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs764206746; called by mutect2, pindel, varscan2
- OR2F2 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 114/614 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371292578, COSV101283812; called by muse, mutect2, varscan2
- OR2T6 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.971); catalogued as rs762508817, COSV100861612, COSV63216953; called by muse, mutect2, varscan2
- OR4E2 | c.455del p.G152Vfs*6 | Frame Shift Del (DEL) | VAF 82/342 reads (24%) | catalogued as rs764448584, COSV100330146; called by mutect2, pindel, varscan2
- OR52N4 | c.401A>T p.Y134F | Missense Mutation (SNP) | VAF 141/618 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100421737; called by muse, mutect2, varscan2
- OR52N5 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372078375, COSV57698725; called by muse, mutect2, varscan2
- OR5H14 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 92/302 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs370923244; called by muse, mutect2, varscan2
- OR5W2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100747706; called by muse, mutect2, varscan2
- OR6S1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780340636, COSV57837458; called by muse, mutect2, varscan2
- OSBPL3 | c.2482C>T p.Q828* | Nonsense Mutation (SNP) | VAF 164/981 reads (17%) | catalogued as COSV100514427; called by muse, varscan2
- OSR2 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs763588260, COSV99882751; called by muse, mutect2, varscan2
- OTOGL | c.1141G>A p.D381N (on ENST00000547103; = p.D372N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV101509470; called by muse, mutect2, varscan2
- P3H3 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99301553; called by muse, mutect2, varscan2
- PAPLN | c.3218del p.P1073Qfs*32 (on ENST00000554301; = p.P1046Qfs*32 on NM_173462.4) | Frame Shift Del (DEL) | VAF 26/109 reads (24%) | catalogued as COSV99390248; called by mutect2, pindel, varscan2
- PARVB | c.653A>G p.H218R | Missense Mutation (SNP) | VAF 60/274 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100115118; called by muse, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 44/144 reads (31%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PAXIP1 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 91/461 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.311); catalogued as COSV101249998; called by muse, mutect2, varscan2
- PCBP2 | c.524del p.P175Rfs*4 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs776329515; called by mutect2, pindel, varscan2
- PCDH12 | c.3175G>T p.A1059S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99191175; called by muse, mutect2, varscan2
- PCDH19 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99720518; called by muse, mutect2
- PCDHB12 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV53396857; called by muse, varscan2
- PCDHB3 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.048); catalogued as rs374259978, COSV99166182; called by muse, mutect2, varscan2
- PCDHB4 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV52020912; called by muse, mutect2, varscan2
- PCDHGA9 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs1182256144, COSV99544081; called by muse, mutect2, varscan2
- PCDHGA9 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as rs377687399; called by muse, mutect2, varscan2
- PCDHGC4 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1272239385, COSV52752660; called by muse, mutect2, varscan2
- PCED1A | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100642927; called by muse, mutect2, varscan2
- PDGFD | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 259/1003 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1364306828, COSV56392319, COSV56398326; called by muse, mutect2, varscan2
- PDGFD | c.640dup p.I214Nfs*5 | Frame Shift Ins (INS) | VAF 72/350 reads (21%) | catalogued as rs1333395128; called by mutect2, varscan2
- PELI1 | c.502-1G>A p.X168_splice | Splice Site (SNP) | VAF 34/158 reads (22%) | catalogued as COSV100735179; called by muse, mutect2, varscan2
- PELP1 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.761); catalogued as COSV99343227; called by muse, mutect2
- PEX6 | c.1132T>C p.W378R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99769928; called by muse, mutect2, varscan2
- PGM1 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 128/456 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV100936649, COSV64299967; called by muse, mutect2, varscan2
- PIGL | c.492G>T p.V164= | Splice Region (SNP) | VAF 71/261 reads (27%) | catalogued as COSV99848785; called by muse, mutect2, varscan2
- PIK3C2A | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV99791087; called by muse, mutect2, varscan2
- PIK3CG | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1462539802, COSV63248803; called by muse, mutect2, varscan2
- PITPNM3 | c.1228A>G p.M410V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99338844; called by muse, mutect2, varscan2
- PIWIL3 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780894038, COSV100177889; called by muse, mutect2, varscan2
- PKHD1L1 | c.12083C>T p.A4028V | Missense Mutation (SNP) | VAF 142/581 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV101006650; called by muse, mutect2, varscan2
- PLCD3 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.885); catalogued as rs757914564, COSV100504386; called by muse, mutect2
- PLEKHG6 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs370357030; called by muse, varscan2
- PLEKHS1 | c.1055dup p.R353Tfs*17 | Frame Shift Ins (INS) | VAF 64/293 reads (22%) | catalogued as rs749797511; called by mutect2, pindel, varscan2
- PLPP5 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773079258, COSV100395593; called by muse, mutect2, varscan2
- PLPPR4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100927074; called by muse, mutect2, varscan2
- PLXDC1 | c.1222+2T>C p.X408_splice | Splice Site (SNP) | VAF 38/98 reads (39%) | catalogued as COSV100195700; called by muse, mutect2, varscan2
- PM20D1 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100900231; called by muse, mutect2, varscan2
- PNPLA5 | c.719G>C p.C240S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV53375057, COSV53375959; called by muse, mutect2, varscan2
- PNPLA8 | c.1453+1G>A p.X485_splice | Splice Site (SNP) | VAF 21/140 reads (15%) | catalogued as COSV99993701; called by muse, mutect2, varscan2
- POLG2 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as COSV56750695; called by muse, mutect2, varscan2
- POLR3B | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 171/660 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99942988; called by muse, mutect2, varscan2
- POMGNT2 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as rs775667995, COSV100768127; called by muse, mutect2, varscan2
- POP1 | c.2254del p.T752Lfs*12 | Frame Shift Del (DEL) | VAF 29/104 reads (28%) | catalogued as rs868622083, COSV62893071; called by mutect2, pindel, varscan2
- PPARA | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.972); catalogued as rs1329872038, COSV53077560, COSV99415811; called by muse, mutect2, varscan2
- PPAT | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV99947431; called by muse, mutect2, varscan2
- PPFIBP1 | c.2192T>C p.I731T (on ENST00000318304 / NM_177444.3; = p.I725T on NM_003622.4) | Missense Mutation (SNP) | VAF 56/505 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179942743, COSV99945273; called by muse, mutect2
- PPIE | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs747872958, COSV100180178; called by muse, mutect2, varscan2
- PPM1A | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 70/353 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as COSV100349351; called by muse, mutect2, varscan2
- PPP1R13B | c.1531del p.Q511Sfs*39 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs758922105; called by mutect2, varscan2
- PPP1R15A | c.849A>T p.E283D | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99566195; called by muse, mutect2, varscan2
- PPP2R2B | c.811C>T p.P271S (on ENST00000394409; = p.P337S on NM_181674.2) | Missense Mutation (SNP) | VAF 175/563 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV100355853; called by muse, mutect2, varscan2
- PPP2R5B | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1210760499, COSV99376363; called by muse, mutect2, varscan2
- PRAG1 | c.2144C>A p.P715H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100422636; called by muse, mutect2, varscan2
- PRAME | c.1505T>G p.L502R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); catalogued as COSV101287204; called by muse, mutect2, varscan2
- PRDM15 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs759441794, COSV54148515; called by muse, mutect2, varscan2
- PRICKLE1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs372213429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKAA1 | c.1084C>A p.L362I | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99713382; called by muse, mutect2, varscan2
- PRKDC | c.10668A>G p.A3556= | Splice Region (SNP) | VAF 30/889 reads (3%) | catalogued as COSV100042209; called by muse, mutect2
- PRKDC | c.8726G>A p.R2909Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100038932, COSV100042212; called by muse, mutect2, varscan2
- PRPF4 | c.1337C>T p.A446V (on ENST00000374198 / NM_001322267.2; = p.A447V on NM_004697.5) | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100950748; called by muse, mutect2, varscan2
- PRR13 | c.18C>T p.A6= | Splice Region (SNP) | VAF 34/1172 reads (3%) | catalogued as COSV101127177; called by muse, mutect2
- PRSS45P | c.743T>A p.L248Q | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV101374025; called by muse, mutect2, varscan2
- PSIP1 | c.1552_1555del p.E518Lfs*5 | Frame Shift Del (DEL) | VAF 50/207 reads (24%) | catalogued as rs748249493; called by mutect2, varscan2
- PTCHD1 | c.1669G>T p.G557W | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV101037933; called by muse, mutect2, varscan2
- PTCHD3 | c.1280T>G p.V427G | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101438950; called by muse, varscan2
- PTK2 | c.3146C>T p.T1049M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.467); catalogued as rs746222859, COSV100570923; called by muse, mutect2, varscan2
- PTPN21 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV60845906; called by muse, mutect2, varscan2
- PTPRC | c.1829G>A p.C610Y | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV100722964, COSV100723335; called by muse, mutect2, varscan2
- PTPRF | c.2154G>T p.E718D | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100741121; called by muse, mutect2, varscan2
- PTPRJ | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as rs767845396, COSV69251802; called by muse, mutect2, varscan2
- PURG | c.533G>T p.R178M | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99989628; called by muse, varscan2
- PWWP3A | c.266G>C p.R89T (on ENST00000627377; = p.R88T on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV100262218; called by muse, mutect2, varscan2
- PXDN | c.3481C>T p.R1161W | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53226287; called by muse, mutect2, varscan2
- PXDNL | c.2767G>C p.G923R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100685473, COSV62479695; called by muse, mutect2, varscan2
- QPRT | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs370631780; called by muse, mutect2, varscan2
- R3HDM2 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV100715474; called by muse, mutect2, varscan2
- RAD1 | c.190T>C p.F64L | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV100337586; called by muse, mutect2, varscan2
- RAG1 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV55025887; called by muse, mutect2, varscan2
- RAI14 | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 97/274 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99464231; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1476del p.F493Sfs*60 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as COSV54576481; called by mutect2, pindel, varscan2
- RARB | c.649C>T p.R217* (on ENST00000383772 / NM_001290216.2; = p.R210* on NM_000965.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 63/232 reads (27%) | catalogued as COSV58066964; called by muse, mutect2, varscan2
- RASGRF2 | c.2773T>C p.W925R | Missense Mutation (SNP) | VAF 127/419 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99429969; called by muse, mutect2, varscan2
- RASSF10 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61754716; called by muse, varscan2
- RASSF8 | c.435A>C p.K145N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV99280930; called by muse, mutect2, varscan2
- RBFOX1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as COSV100303007; called by muse, mutect2, varscan2
- RBFOX2 | c.1018G>A p.A340T (on ENST00000438146 / NM_001349995.2; = p.A266T on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs1373405959, COSV53267757; called by muse, mutect2, varscan2
- RBM15 | c.2663T>A p.L888H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873490; called by muse, mutect2, varscan2
- RBM18 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 128/574 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101313794; called by mutect2, varscan2
- RCBTB1 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs374135653, COSV51638333; called by muse, mutect2, varscan2
- RCOR3 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs773567709, COSV100879637; called by muse, mutect2, varscan2
- RECQL5 | c.1719A>C p.E573D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV100512231; called by muse, mutect2, varscan2
- REV3L | c.8590C>A p.P2864T | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100725560; called by muse, mutect2, varscan2
- RFPL3 | c.839G>A p.R280H (on ENST00000249007 / NM_001098535.1; = p.R251H on NM_006604.2) | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.576); catalogued as rs140074264, COSV50747916; called by muse, varscan2
- RGS14 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV68771445; called by muse, mutect2, varscan2
- RHOT1 | c.541-1G>T p.X181_splice | Splice Site (SNP) | VAF 32/191 reads (17%) | catalogued as COSV100447510; called by muse, mutect2, varscan2
- RIF1 | c.4322del p.K1441Rfs*18 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs767284433; called by pindel, varscan2
- RILPL2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753404340, COSV54913611; called by muse, varscan2
- RNF123 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100571077; called by muse, varscan2
- RNF14 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100641278; called by muse, mutect2, varscan2
- RNF150 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as rs974188903, COSV100153968; called by muse, mutect2, varscan2
- RNF216 | c.686G>C p.G229A (on ENST00000425013 / NM_207116.3; = p.G286A on NM_207111.4) | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.311); catalogued as COSV101111363; called by muse, mutect2, varscan2
- RNF34 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs369744966; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNPS1 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as rs777754533, COSV100067633; called by mutect2, varscan2
- RP1 | c.4328G>A p.R1443Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs759930573, CM153506, COSV99608414; called by muse, mutect2, varscan2
- RP9 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 96/567 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51807577; called by muse, mutect2, varscan2
- RPA1 | c.1493A>G p.Y498C | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99628273; called by muse, mutect2, varscan2
- RPL18A | c.527_529del p.F176del | In Frame Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs761463624; called by pindel, varscan2
- RPL34 | c.*5del | Frame Shift Del (DEL) | VAF 26/123 reads (21%) | catalogued as rs761738263; called by mutect2, pindel, varscan2
- RPS6KA3 | c.1840G>A p.G614S | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772004070, COSV65388317, COSV65388531; called by muse, mutect2, varscan2
- RPS6KB2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.273); catalogued as rs370932588, COSV57055903; called by muse, varscan2
- RTL8C | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99924364; called by mutect2, varscan2
- RTN1 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs759537844, COSV99956524; called by muse, mutect2, varscan2
- RYR1 | c.14725G>A p.E4909K | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs780237633, COSV100616616; called by muse, mutect2, varscan2
- SAG | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs760031511, COSV68590968; called by muse, mutect2, varscan2
- SAGE1 | c.635A>G p.E212G | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100187710; called by muse, mutect2, varscan2
- SAMD9L | c.3521del p.N1174Tfs*28 | Frame Shift Del (DEL) | VAF 96/462 reads (21%) | catalogued as rs1197717436; called by mutect2, pindel, varscan2
- SBF1 | c.5600G>A p.R1867H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1241548260, COSV53295362; called by muse, mutect2, varscan2
- SCAF4 | c.3007_3009del p.R1003del | In Frame Del (DEL) | VAF 92/392 reads (23%) | catalogued as rs762039419; called by pindel, varscan2
- SCAF4 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.048); catalogued as rs765125794, COSV54255511; called by muse, mutect2, varscan2
- SCD | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs200630764, COSV64853157; called by muse, mutect2, varscan2
- SCLY | c.1286G>A p.S429N (on ENST00000651534; = p.S421N on NM_016510.7) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs752788709, COSV99616135; called by muse, mutect2, varscan2
- SCML4 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100940418; called by muse, mutect2, varscan2
- SCN3A | c.4763G>C p.G1588A | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV104393142, COSV99327988; called by muse, mutect2, varscan2
- SCN3A | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs965476894, COSV51822082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNM1 | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 221/905 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99766162; called by muse, mutect2, varscan2
- SDF2 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99897975; called by muse, mutect2, varscan2
- SDK1 | c.4004C>T p.T1335M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs140791078, COSV101268661; called by muse, mutect2, varscan2
- SDK1 | c.4718C>T p.T1573M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs150578081; called by muse, mutect2, varscan2
- SEC16A | c.1891G>A p.V631M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as rs1262761726, COSV99259847; called by muse, mutect2, varscan2
- SEC63 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 143/615 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754604388, COSV100938443; called by muse, mutect2, varscan2
- SEMA4D | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1287280571, COSV100358666; called by muse, mutect2, varscan2
- SERINC2 | c.280T>C p.Y94H (on ENST00000373709 / NM_178865.5; = p.Y98H on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs782371695, COSV101037086; called by muse, mutect2, varscan2
- SERP1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53525395, COSV99526574; called by muse, mutect2, varscan2
- SERP2 | c.120G>C p.W40C | Missense Mutation (SNP) | VAF 529/2286 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV101002086, COSV64851781; called by muse, mutect2, varscan2
- SETD1A | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as rs1294234824, COSV99353536; called by muse, mutect2, varscan2
- SETD7 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 213/577 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750730311, COSV99918649; called by muse, mutect2, varscan2
- SFPQ | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs958417932, COSV61758340; called by muse, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SH3KBP1 | c.1286T>C p.L429P | Missense Mutation (SNP) | VAF 228/396 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101115065; called by muse, mutect2, varscan2
- SHC2 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs528045997, COSV99199101; called by muse, mutect2, varscan2
- SHF | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs140713703; called by muse, mutect2, varscan2
- SHMT2 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1040216145, COSV100197316; called by muse, mutect2, varscan2
- SHROOM4 | c.2528C>T p.S843L | Missense Mutation (SNP) | VAF 67/861 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99174176; called by muse, mutect2
- SIAH2 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs748812007, COSV100469396; called by mutect2, varscan2
- SIGLEC9 | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99143070; called by muse, mutect2, varscan2
- SIPA1L1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.629); catalogued as COSV62169645; called by muse, mutect2, varscan2
- SIX1 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs779084301, COSV55960211; called by muse, mutect2, varscan2
- SKP1 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 87/289 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV100104605; called by muse, mutect2, varscan2
- SLC12A5 | c.2407C>T p.R803C (on ENST00000454036 / NM_001134771.2; = p.R780C on NM_020708.5) | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs757395459, COSV54788236; called by muse, mutect2, varscan2
- SLC12A9 | c.46del p.E16Rfs*39 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | catalogued as rs768992853; called by mutect2, pindel, varscan2
- SLC16A2 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 189/682 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs765020281, COSV99330974; called by muse, varscan2
- SLC17A4 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100930652; called by muse, mutect2, varscan2
- SLC18B1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99259272; called by muse, mutect2, varscan2
- SLC22A10 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 271/889 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs374307478; called by muse, mutect2, varscan2
- SLC22A14 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1078846, COSV99828319; called by muse, mutect2, varscan2
- SLC22A3 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1043162832, COSV51709731; called by muse, mutect2, varscan2
- SLC22A7 | c.970G>A p.A324T (on ENST00000372585 / NM_153320.2; = p.A322T on NM_006672.3) | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs202177785; called by muse, mutect2, varscan2
- SLC24A5 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 130/421 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99981983; called by muse, mutect2, varscan2
- SLC25A12 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763454149, COSV99785320; called by muse, mutect2, varscan2
- SLC25A51 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1341101846, COSV99643278; called by muse, mutect2, varscan2
- SLC35G2 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101262082; called by muse, mutect2
- SLC49A3 | c.660del p.T221Pfs*39 (on ENST00000404286 / NM_001294341.2; = p.T221Pfs*38 on NM_032219.4) | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as rs762838637; called by mutect2, varscan2
- SLC4A5 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs765679180, COSV61024422; called by muse, mutect2, varscan2
- SLC66A1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs546350739, COSV64321025; called by muse, mutect2, varscan2
- SLC8A1 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245804817, COSV100247060; called by muse, mutect2
- SLF1 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 336/1176 reads (29%) | catalogued as rs370026748, COSV54371474; called by muse, varscan2
- SLIT1 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759543634, COSV56600896; called by muse, mutect2, varscan2
- SLK | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100212029; called by muse, mutect2, varscan2
- SLPI | c.306del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 31/138 reads (22%) | catalogued as rs745834619; called by mutect2, pindel, varscan2
- SLTM | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs765954420, COSV100998628; called by muse, mutect2, varscan2
- SMARCAL1 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.039); catalogued as COSV100620015; called by muse, mutect2, varscan2
- SMC1A | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM096583, COSV100447625; called by muse, mutect2, varscan2
- SMC4 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as rs776113181, COSV100644108; called by muse, mutect2, varscan2
- SMC5 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 91/351 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs768926946, COSV100747148; called by muse, mutect2, varscan2
- SMCHD1 | c.2040del p.K680Nfs*3 | Frame Shift Del (DEL) | VAF 35/173 reads (20%) | catalogued as rs766211852; called by mutect2, pindel, varscan2
- SMTNL1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as rs950686234, COSV101216503; called by muse, mutect2, varscan2
- SNAP29 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs1434446076, COSV99300924; called by muse, mutect2, varscan2
- SNCAIP | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV99749693, COSV99749793; called by muse, mutect2, varscan2
- SND1 | c.747A>T p.K249N | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100690911; called by muse, mutect2, varscan2
- SORBS2 | c.244G>A p.G82R (on ENST00000284776 / NM_021069.5; = p.G128R on NM_003603.6) | Missense Mutation (SNP) | VAF 134/543 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756045058, COSV99512191; called by muse, mutect2, varscan2
- SOX21 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100977929; called by muse, mutect2, varscan2
- SPOCK1 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV99970446; called by muse, mutect2, varscan2
- SPOP | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV100753522; called by muse, mutect2, varscan2
- SPPL3 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1440965481, COSV62232669; called by muse, varscan2
- SPPL3 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748637155; called by muse, varscan2
- SPRY4 | c.235G>A p.A79T (on ENST00000434127 / NM_001127496.3; = p.A102T on NM_030964.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs755750768, COSV59986876; called by muse, mutect2, varscan2
- SPTBN4 | c.5978C>T p.A1993V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs765019377, COSV58948089; called by muse, mutect2, varscan2
- SRRM1 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 21/111 reads (19%) | catalogued as COSV100105019; called by muse, mutect2, varscan2
- SRSF10 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.767); catalogued as COSV100087085, COSV58361478; called by muse, mutect2, varscan2
- SSR1 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 140/412 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99783791; called by muse, mutect2, varscan2
- ST3GAL1 | c.304C>T p.L102= | Splice Region (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100172410; called by muse, varscan2
- STAG3 | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV100426125; called by muse, mutect2, varscan2
- STARD13 | c.1243C>A p.L415I (on ENST00000336934 / NM_001243476.3; = p.L297I on NM_052851.3) | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV55228051; called by muse, mutect2, varscan2
- STC1 | c.603C>A p.H201Q | Missense Mutation (SNP) | VAF 130/414 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.093); catalogued as COSV99282677; called by muse, mutect2, varscan2
- STS | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 105/331 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1032020820, COSV99481567; called by muse, mutect2, varscan2
- STXBP1 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.773); catalogued as rs750968891, COSV64814678; ClinVar: likely benign; called by muse, mutect2, varscan2
- SUSD1 | c.1667T>C p.L556P | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100813454; called by muse, mutect2, varscan2
- SYN2 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs768831881; called by muse, mutect2, varscan2
- SYT5 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV62829763; called by muse, mutect2, varscan2
- TAF1D | c.281del p.K94Rfs*26 | Frame Shift Del (DEL) | VAF 54/202 reads (27%) | catalogued as rs746556335; called by mutect2, varscan2
- TAF2 | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.279); catalogued as COSV100978777; called by muse, mutect2, varscan2
- TAF4 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs750428794; called by muse, mutect2, varscan2
- TANC1 | c.2742G>A p.K914= | Splice Region (SNP) | VAF 31/106 reads (29%) | catalogued as rs748573576, COSV99713264; called by muse, mutect2, varscan2
- TAP2 | c.1600A>G p.I534V | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV66498599; called by muse, mutect2, varscan2
- TBC1D14 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as rs771221755, COSV99056086; called by muse, mutect2, varscan2
- TBC1D17 | c.1259T>C p.M420T | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs202133410, COSV99680874; called by muse, mutect2, varscan2
- TBL1XR1 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100763621; called by muse, mutect2, varscan2
- TBRG4 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV51833535; called by muse, mutect2
- TBXAS1 | c.16T>C p.F6L | Missense Mutation (SNP) | VAF 111/653 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV54946829; called by muse, mutect2, varscan2
- TCEA2 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1334229823, COSV100200408; called by muse, mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 61/307 reads (20%) | catalogued as COSV61906772; called by mutect2, pindel, varscan2
- TECPR1 | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405666696, COSV101130669; called by muse, mutect2, varscan2
- TEKT4 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs782695306, COSV99726609; called by muse, mutect2, varscan2
- TENM2 | c.4829C>T p.T1610I (on ENST00000518659 / NM_001122679.2; = p.T1371I on NM_001080428.3) | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101319339; called by muse, mutect2, varscan2
- TENM2 | c.5174G>A p.R1725Q (on ENST00000518659 / NM_001122679.2; = p.R1486Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.347); catalogued as rs755957556, COSV69129785; called by muse, mutect2, varscan2
- TENT4A | c.2335C>A p.H779N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs748296365, COSV50094534; called by muse, mutect2, varscan2
- TEP1 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548257852, COSV99403005; called by muse, mutect2, varscan2
- TEX14 | c.3746A>G p.E1249G (on ENST00000240361 / NM_001201457.2; = p.E1203G on NM_031272.5) | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99543153; called by muse, mutect2, varscan2
599 further variants in this file (249 protein-altering or splice-affecting, 332 silent, 18 other) are not listed here.
